Somatic mutation profile of tumor specimen MBCProject_0128_T1_WES (aliquot MBCProject_0128_T1_WES_1) from CMI case MBCProject_0128, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 37.1 years (13,553 days).
Specimen MBCProject_0128_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77f06030-06da-4c98-9ff7-c52cdb73eef1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0128_SALIVA (Saliva), aliquot MBCProject_0128_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c797e281-5e33-4812-9473-db4a73dcf332

The open-access MAF lists 32 somatic variants for this specimen: 23 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 5, Intron 3, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 67/261 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.331A>G p.K111E | Missense Mutation (SNP) | VAF 11/35 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs1057519933, COSV55878486, COSV56029794; ClinVar: likely pathogenic; called by muse, varscan2
- ABCB4 | c.2402G>A p.S801N | Missense Mutation (SNP) | VAF 48/262 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs766122347; called by muse, mutect2, varscan2
- BCAP31 | c.230C>T p.T77M | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.426); catalogued as rs782018233, COSV100798979; called by muse, mutect2, varscan2
- DNAI1 | c.619C>T p.R207W | Missense Mutation (SNP) | VAF 50/206 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749119217; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- F2 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as rs777315807, COSV61315666; called by muse, mutect2, varscan2
- FLG | c.11095C>T p.R3699W | Missense Mutation (SNP) | VAF 50/460 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.965); catalogued as rs748562991; called by muse, mutect2, varscan2
- JPH2 | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs747893109, COSV60697447; called by muse, mutect2, varscan2
- MECOM | c.1811G>A p.R604Q (on ENST00000468789 / NM_001105078.4; = p.R792Q on NM_004991.4) | Missense Mutation (SNP) | VAF 47/260 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as rs753395114, COSV52961431; called by muse, mutect2, varscan2
- MET | c.4091C>T p.P1364L | Missense Mutation (SNP) | VAF 32/214 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752791731, COSV59270568; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYOM2 | c.4057G>A p.V1353M | Missense Mutation (SNP) | VAF 46/335 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs752562809, COSV100037469; called by muse, mutect2, varscan2
- NRIP1 | c.1177A>G p.M393V | Missense Mutation (SNP) | VAF 33/229 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs775003588; called by muse, mutect2, varscan2
- PIAS3 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 156/450 reads (35%) | catalogued as rs868988923, COSV65171507; called by muse, mutect2, varscan2
- PUDP | c.187G>C p.D63H | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as rs1396281283; called by muse, mutect2
- SLIT1 | c.1954G>A p.V652I | Missense Mutation (SNP) | VAF 48/466 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759325625, COSV56584365; called by muse, mutect2
- ATF7IP | c.2984C>G p.S995C | Missense Mutation (SNP) | VAF 28/278 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.634); called by muse, mutect2
- CCDC51 | c.956G>A p.G319D | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- DOCK11 | c.1787A>T p.D596V | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- HNF1A | c.659G>C p.R220T | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.265); called by muse, mutect2
- LAMC3 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PCDH18 | c.2494T>C p.S832P | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TRPM2 | c.98T>C p.L33P | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TRPV4 | c.1564G>C p.V522L | Missense Mutation (SNP) | VAF 21/432 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.02); called by muse, mutect2
- AP2B1 | c.1422C>T p.H474= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs925357404; called by muse, mutect2, varscan2
- CACNA1H | c.3732C>T p.D1244= | Silent (SNP) | VAF 36/235 reads (15%) | catalogued as rs755463348, COSV61989311; called by muse, mutect2, varscan2
- CBLIF | c.418T>C p.L140= | Silent (SNP) | VAF 26/284 reads (9%) | catalogued as rs141917734, COSV57240078; called by muse, mutect2
- GLIS2 | c.1479C>T p.G493= | Silent (SNP) | VAF 47/339 reads (14%) | catalogued as rs373227853; called by muse, mutect2, varscan2
- VAC14 | c.1008C>T p.D336= | Silent (SNP) | VAF 29/127 reads (23%) | catalogued as rs747778595; called by muse, mutect2, varscan2
- FAM20A | c.*461_*462del | 3'UTR (DEL) | VAF 12/78 reads (15%) | called by mutect2, pindel, varscan2
- MBP | c.750+311G>A | Intron (SNP) | VAF 15/54 reads (28%) | catalogued as rs770772185; called by muse, mutect2, varscan2
- MID1 | c.757-10756G>T | Intron (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- TRIM24 | c.364+336C>A | Intron (SNP) | VAF 22/246 reads (9%) | called by muse, mutect2
